CCDI case PBBVKJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/36693e31-a66c-4248-9c38-87947b34654f

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.0 years (352 days).

Biospecimens (3 samples)
- Sample 0DII34: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
